TCGA case TCGA-32-2616 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital (AZ). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/52408d9f-2637-4952-9b90-cb607a860f23

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 224 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 48.7 years (17,781 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 71 days; Treatment dose: 5,590 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Motexafin Gadolinium; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 51 days; Treatment dose: 50,167 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 72 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 101 days; Days to treatment end: 105 days; Number of cycles: 1; Treatment dose: 1,350 mg; Prescribed dose: 270; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 129 days; Days to treatment end: 161 days; Number of cycles: 2; Treatment dose: 360 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 189 days; Days to treatment end: 203 days; Treatment dose: 3,000 cGy; Number of fractions: 10; Treatment anatomic sites: Locoregional Site.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 49.2 years (17,963 days); Days to diagnosis: 182 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 182 (post initial treatment): Progression or recurrence: Yes; Days to progression: 182 days.
- Days to follow up: 224 days; Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-32-2616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-32-2616-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-32-2616-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
- Sample TCGA-32-2616-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Motexatin Gadoinium.
- Drug treatment 3, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 224 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 224 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 182 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-32-2616-01A-01D-0911-01): tumor purity 0.83, ploidy 2.05, whole-genome doublings 0.
